TCGA case TCGA-AX-A0IU — Uterine Corpus Endometrial Carcinoma (TCGA-UCEC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Corpus uteri; Tissue source site: Gynecologic Oncology Group. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/7e64ea6c-a3db-48eb-91be-131361510a92

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 79 years; Vital status: Alive.

Diagnoses (1)
1. Serous cystadenocarcinoma, NOS: ICD-O-3 morphology code: 8441/3; ICD-10 code: C54.1; Tissue or organ of origin: Endometrium; Site of resection or biopsy: Endometrium; Classification of tumor: primary; Age at diagnosis: 79.6 years (29,063 days); Year of diagnosis: 2008; Method of diagnosis: Biopsy; FIGO stage: Stage IIIC; FIGO staging edition year: 1988; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 1,087 days (3.0 years).
   Pathology details: Consistent pathology review: Yes; Percent tumor invasion: 50.
   Pathology details: Lymph node involved site: Pelvis, NOS; Lymph nodes positive: 1; Lymph nodes tested: 7.
   Pathology details: Lymph node involved site: Aortic; Lymph nodes positive: 1; Lymph nodes tested: 6.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 64 days; Number of cycles: 5.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Days to treatment start: 64 days; Clinical trial indicator: Yes.
   Treatment given: Treatment type: Surgery, Open; Initial disease status: Initial Diagnosis.
   Recorded, whether given is unknown: Pharmaceutical Therapy, NOS (Tamoxifen), prior to diagnosis.

Follow-up (3 entries)
- Days to follow up: 868 days (2.4 years); Disease response: Tumor Free.
- Peritoneal washing results: Negative; Timepoint: Initial Diagnosis.
- Follow-up contact recording only the day: day 1,087.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 76 kg; Height: 158 cm; BMI: 30.4.
- Timepoint category: Prior to Diagnosis; Menopause status: Postmenopausal; Risk factors: Diabetes, NOS / Hypertension.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-AX-A0IU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 240 mg.
  Slide TCGA-AX-A0IU-01A-01-MS1: Section location: Top; Percent tumor cells: 45; Percent tumor nuclei: 60; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 45; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 4; Percent neutrophil infiltration: 2.
  Slide TCGA-AX-A0IU-01A-01-BS1: Section location: Bottom; Percent tumor cells: 55; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 30; Percent stromal cells: 15; Percent lymphocyte infiltration: 7; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 1.
- Sample TCGA-AX-A0IU-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-AX-A0IU-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); History neoadjuvant treatment: No; Tumor status: Tumor free; Submitted tumor site: Endometrial; Histologic diagnosis: Serous endometrial adenocarcinoma; Method initial path diagnosis: Office Endometrial Biopsy; Surgical approach at diagnosis: open.
- Follow-up form 1: Hypertension diagnosis: Yes; Diabetes diagnosis indicator: Yes; History colorectal cancer: No; Treatment outcome first course: Complete Remission/Response; Tumor status: Tumor free.
- Follow-up form 2: Lost to follow-up: Yes; Treatment outcome at TCGA followup: Complete Response.
- Drug treatment 1: Regimen number: 1.
- Drug treatment 2: Clinical trial drug classification: adjuvent.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,087 days; disease-specific survival: no event (censored), 1,087 days; disease-free interval: no event (censored), 1,087 days; progression-free interval: no event (censored), 1,087 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-AX-A0IU-01A-11D-A102-01): tumor purity 0.79, ploidy 2.18, whole-genome doublings 0.
